Gene-level copy-number profile of specimen HCM-SANG-0778-C25-85A-01D-A80T-32 from HCMI case HCM-SANG-0778-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2.
Specimen HCM-SANG-0778-C25-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e1ef9327-ba71-485d-b322-f76b32e4f182.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0778-C25-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/0ae3de2e-9122-4963-b5b4-1e468f4f8162

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 5; copy number 2: 2,306; copy number 3: 93; copy number 4: 20,994; copy number 5: 10,251; copy number 6: 12,959; copy number 7: 6,775; copy number 8: 3,402; copy number 9: 879; copy number 10: 237; copy number 11: 296; copy number 12: 140; copy number 13: 42; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,596 genes in 71 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,842,875–150,476,566, 25 genes, copy number 11 (within-gene range 6–11): H2BC19P, H2BC20P, H2BC21, H2AC20, H2AC21, BOLA1, SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2.
- chr2:123,443,266–123,869,570, 5 genes, copy number 12: AC073409.1, ELOAP1, PSMD14P1, AC064859.1, RN7SKP102.
- chr2:138,501,770–139,511,555, 11 genes, copy number 10: SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4, AC062021.1, AC016710.1, SNORA72.
- chr2:182,909,115–183,215,414, 8 genes, copy number 10: NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35, AC021851.1.
- chr2:203,394,345–206,420,238, 46 genes, copy number 10 (within-gene range 7–10): RAPH1, AC125238.2, AC125238.1, CD28, KRT18P39, NPM1P33, RNU6-474P, CTLA4, ICOS, AC009965.2, AC009965.1, AC009498.1, DSTNP5, AC106901.1, AC016903.1, AC016903.2, PARD3B, AC007736.1, AC008171.1, NRP2, AC007362.1, RN7SKP178, PPIAP68, AC007679.1, INO80D, Vault, Y_RNA, RPL27P8, AC007383.1, NDUFS1, AC007383.2, GCSHP3, EEF1B2, AC007383.3, snoZ196, SNORD51, SNORA41, GPR1, GPR1-AS, RN7SKP200, ATP5POP1, HMGN1P6, RN7SKP260, ZDBF2, ACER2P1, HNRNPA1P51.
- chr3:18,345,377–19,702,795, 8 genes, copy number 9 (within-gene range 7–9): SATB1, AC144521.1, SATB1-AS1, RAD23BP1, RNU6-138P, KCNH8, MIR4791, AC061958.1.
- chr3:56,727,418–57,942,304, 27 genes, copy number 9–12: ARHGEF3, ARHGEF3-AS1, SPATA12, AC097358.2, IL17RD, AC097358.1, HESX1, APPL1, ASB14, AC093928.1, DNAH12, Y_RNA, RNU6-1181P, RNF7P1, AC092418.1, RNU6-108P, RNU6-483P, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P, DENND6A, DENND6A-AS1, DENND6A-DT, SLMAP, PDHA1P1, PPIAP16.
- chr3:167,683,298–168,830,599, 15 genes, copy number 10–11 (within-gene range 7–11): PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B.
- chr3:184,026,369–187,449,450, 106 genes, copy number 11 (broad region; genes not listed).
- chr6:43,427,366–44,553,281, 47 genes, copy number 9: ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2.
- chr6:70,856,679–72,403,143, 20 genes, copy number 9–10 (within-gene range 8–10): B3GAT2, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.1, KRT19P1, RNU4-66P, RIMS1.
- chr7:16,599,779–16,888,885, 10 genes, copy number 9: ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2.
- chr7:33,904,308–35,038,271, 12 genes, copy number 10: BMPER, AC007350.1, AC009262.1, RNU6-438P, NPSR1-AS1, NPSR1, RPL7P31, NCAPD2P1, RN7SL132P, AC004788.1, DPY19L1, MIR548N.
- chr7:56,597,379–56,882,146, 8 genes, copy number 9: AC092447.1, AC092447.9, TRIM60P16, AC095038.1, AC095038.2, CICP28, AC118758.2, AC118758.1.
- chr7:92,245,974–95,296,415, 54 genes, copy number 10 (within-gene range 6–10): ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2, AC002074.1, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P.
- chr8:127,086,263–128,187,101, 18 genes, copy number 9–14 (within-gene range 4–14): AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207.
- chr8:140,657,900–141,518,737, 23 genes, copy number 9–12: PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.1.
- chr9:101,334,084–101,482,199, 10 genes, copy number 9 (within-gene range 4–9): ACNATP, BAAT, TRMT112P4, AL359893.1, FYTTD1P1, MRPL50, ZNF189, ALDOB, AL353621.2, TMEM246-AS1.
- chr10:102,714,538–103,855,543, 41 genes, copy number 9–10: SFXN2, WBP1L, RNU6-1231P, CYP17A1, PFN1P11, PTGES3P4, AL358790.1, BORCS7, BORCS7-ASMT, U6, AS3MT, RPL22P17, AL356608.3, AL356608.1, CNNM2, AL356608.2, NT5C2, RPS15AP29, MARCKSL1P1, ST13P13, RPEL1, INA, PCGF6, RNU11-3P, TAF5, ATP5MD, MIR1307, PDCD11, CALHM2, AL139339.2, AL139339.1, CALHM1, CALHM3, NEURL1-AS1, NEURL1, AL121929.1, AL121929.3, SH3PXD2A, AL121929.2, Y_RNA, SH3PXD2A-AS1.
- chr10:113,353,425–128,320,214, 242 genes, copy number 9–13 (broad region; genes not listed).
- chr10:132,433,733–133,778,699, 65 genes, copy number 9 (broad region; genes not listed).
- chr11:63,506,052–63,671,921, 8 genes, copy number 9–11: LGALS12, PLAAT4, PLAAT2, PLAAT3, AP000753.1, ATL3, IMMP1LP1, AP000753.2.
- chr11:76,349,956–76,804,555, 17 genes, copy number 11: THAP12, GVQW3, Y_RNA, AP002360.1, EMSY, AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3.
- chr11:101,129,077–103,045,712, 43 genes, copy number 10 (within-gene range 6–10): PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1.
- chr12:26,120,030–26,421,462, 10 genes, copy number 12 (within-gene range 6–12): BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1.
- chr12:97,679,879–98,735,433, 17 genes, copy number 10–14 (within-gene range 6–14): AC018659.2, PAFAH1B2P2, RNU6-36P, MIR4495, MIR4303, AC016152.1, AC008055.1, RNU4-41P, SLC9A7P1, LINC02453, TMPO-AS1, TMPO, PPIAP8, SLC25A3, SNORA53, IKBIP, APAF1.
- chr13:38,902,387–39,223,238, 6 genes, copy number 11–12 (within-gene range 7–12): PLA2G12AP2, ANKRD26P2, STOML3, PROSER1, NHLRC3, AL354809.1.
- chr13:71,913,704–74,830,080, 35 genes, copy number 10–13: RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12, AL138713.1, AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1.
- chr14:18,333,726–20,415,098, 113 genes, copy number 9–11 (broad region; genes not listed).
- chr14:21,894,433–23,057,538, 149 genes, copy number 9 (broad region; genes not listed).
- chr17:4,583,999–5,028,401, 41 genes, copy number 9: SMTNL2, LINC01996, RNU6-955P, ALOX15, PELP1, AC091153.2, AC091153.3, AC091153.1, ARRB2, MED11, AC091153.4, CXCL16, ZMYND15, TM4SF5, VMO1, AC233723.2, GLTPD2, PSMB6, AC233723.1, PLD2, MINK1, ATP6V0CP1, RN7SL784P, CHRNE, C17orf107, GP1BA, SLC25A11, RNF167, PFN1, ENO3, SPAG7, CAMTA2, AC004771.3, MIR6864, MIR6865, AC004771.1, AC004771.4, AC004771.2, INCA1, KIF1C, KIF1C-AS1.
- chr17:36,495,633–38,405,593, 53 genes, copy number 11 (within-gene range 10–11): MYO19, PIGW, GGNBP2, AC243732.1, DHRS11, MRM1, AC243830.2, AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7.
- chr18:21,871,446–22,647,688, 18 genes, copy number 9: AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P.
- chr18:68,427,030–69,055,189, 11 genes, copy number 9 (within-gene range 8–9): AC005909.1, AKR1B10P2, MTL3P, TMX3, CCDC102B, AC040896.1, AC022035.1, RNU6-39P, SDHCP1, AC096708.2, AC096708.3.
- chr18:69,831,158–71,011,490, 14 genes, copy number 9 (within-gene range 8–9): CD226, RTTN, AC021701.1, SOCS6, LINC01909, LIVAR, LINC01910, LARP7P3, RPS2P6, AC091305.1, AC091646.1, RN7SL795P, GTSCR1, AC090415.2.
- chr18:72,742,314–73,745,232, 9 genes, copy number 9: NETO1, AC023301.1, RNA5SP460, MIR548AV, AC091138.1, LINC02864, LINC02582, AC079070.1, RN7SL401P.
- chr19:8,778,665–10,713,437, 106 genes, copy number 12 (broad region; genes not listed).
- chr19:15,564,074–16,817,963, 78 genes, copy number 9–11 (broad region; genes not listed).
- chr19:18,001,132–18,049,090, 5 genes, copy number 10: ARRDC2, AC020904.3, AC020904.2, AC020904.1, RPS18P13.
- chr19:55,132,698–55,209,506, 8 genes, copy number 10: TNNT1, TNNI3, AC010327.2, DNAAF3, AC010327.4, AC010327.1, SYT5, PTPRH.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
